Somatic mutation profile of tumor specimen MP2PRT-PAUMBS-TBP1-A (aliquot MP2PRT-PAUMBS-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUMBS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,485 days).
Specimen MP2PRT-PAUMBS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb837043-a971-42d5-8b95-f64494e6d7d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMBS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMBS-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7326c0b2-3679-48cb-8294-6455942c3a80

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC9 | c.210G>A p.S70= | Splice Region (SNP) | VAF 20/368 reads (5%) | catalogued as rs372711525; called by muse, mutect2
- C6 | c.232T>G p.C78G | Missense Mutation (SNP) | VAF 22/554 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MRE11 | c.235T>A p.L79I | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2
- PSMC3 | c.1099C>G p.Q367E | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.257); called by muse, mutect2
- PCDHA1 | c.1554C>T p.Y518= | Silent (SNP) | VAF 52/1038 reads (5%) | catalogued as rs782115801; called by muse, mutect2
